TARGET case TARGET-52-PAUHAZ — Rhabdoid Tumor (TARGET-RT)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Complex Mixed and Stromal Neoplasms; Primary site: Kidney. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/33c9c596-9412-54ff-8902-5b8060fded60

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 0 years; Vital status: Alive.

Diagnoses (1)
1. Malignant rhabdoid tumor: ICD-O-3 morphology code: 8963/3; ICD-10 code: C64; Tissue or organ of origin: Kidney, NOS; Classification of tumor: primary; Age at diagnosis: 0.7 years (239 days); Year of diagnosis: 2011; Days to last follow up: 198 days; Pediatric kidney staging: Nephrectomy specimen with tumor that is present at the surgical margin of resection or within regional lymph nodes, no distant metastasis.
   Treatment given: Protocol identifier: AREN03B2.

Follow-up (1 entry)
- Days to follow up: 198 days; Event-free: no event (relapse, second malignancy or death) recorded through day 198; Year of follow up: 2012.

Biospecimens (2 samples)
- Sample TARGET-52-PAUHAZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-52-PAUHAZ-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_RT_ClinicalData_Discovery_20230322.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 198
- Stage: III
- ICD-O-3-T: C649
- Histologic Classification of Primary Tumor: RT

Additional fields from the TARGET clinical supplement workbook TARGET_RT_ClinicalData_Discovery_and_Validation_Percent_Tumor_Nuclei_and_Necrosis_Supplement_20230322.xlsx (sheet RT Data), for sample TARGET-52-PAUHAZ-01A-01:
- Histological Subtype: rhabdoid
- Specimen Type: frozen solid tumor
- Adequate Tissue (Y/N): Y
- Pathology: Diagnosis Confirmed: yes
- % Tumor Nuclei: Top: 85
- % Non tumor Nuclei: Top: 15
- % Cellular Tumor: Top: 80
- % Normal: Top: 0
- % Stroma: Top: 20
- % Necrosis: Top: 0
- % Tumor Nuclei: Bottom: 95
- % Non tumor Nuclei: Bottom: 5
- % Cellular Tumor: Bottom: 95
- % Normal: Bottom: 0
- % Stroma: Bottom: 5
- % Necrosis: Bottom: 0
- Pathology Pass/Fail: pass

Additional fields from the TARGET clinical supplement workbook TARGET_RT_ClinicalData_Discovery_and_Validation_Percent_Tumor_Nuclei_and_Necrosis_Supplement_20230322.xlsx (sheet RT Data), for sample TARGET-52-PAUHAZ-01A-02:
- Histological Subtype: rhabdoid
- Specimen Type: frozen solid tumor
- Adequate Tissue (Y/N): Y
- Pathology: Diagnosis Confirmed: yes
- % Tumor Nuclei: Top: 95
- % Non tumor Nuclei: Top: 5
- % Cellular Tumor: Top: 75
- % Normal: Top: 0
- % Stroma: Top: 5
- % Necrosis: Top: 20
- % Tumor Nuclei: Bottom: 95
- % Non tumor Nuclei: Bottom: 5
- % Cellular Tumor: Bottom: 80
- % Normal: Bottom: 0
- % Stroma: Bottom: 5
- % Necrosis: Bottom: 10
- Pathology Pass/Fail: pass

Additional fields from the TARGET clinical supplement workbook TARGET_RT_ClinicalData_Discovery_and_Validation_Supplement_20230322.xlsx, for sample TARGET-52-PAUHAZ-01A-01D:
- Cohort: Discovery
- Tumour content estimated by APOLLOH (%): 86.91
- Anatomical site of matched normal: Peripheral blood
- Stage of the primary tumour at the time of diagnosis: 3
